Somatic mutation profile of tumor specimen 0DPDI7 from CCDI case PBCDFE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.9 years (705 days).
Specimen 0DPDI7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db13593e-1c75-4218-868f-43a484f825a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPDHA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00ab97d4-4ef3-4e32-8a9b-be1a989f2693

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FCGBP | c.2429C>A p.P810Q | Missense Mutation (SNP) | VAF 205/631 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 44/1199 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 12/272 reads (4%) | called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 11/120 reads (9%) | called by muse, varscan2
